Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6936, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6936-01A (Primary Tumor).

[page 1 of 5]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT NECK DISSECTION, LEVEL 1A:
One lymph node, no tumor present.
- (B) RIGHT NECK DISSECTION, LEVEL 1B:
METASTATIC CARCINOMA PRESENT IN SOFT TISSUE.
METASTATIC CARCINOMA PRESENT IN ONE OF ONE LYMPH NODE (1/1).
Submandibular gland, no tumor present.
- (C) RIGHT LEVEL 2A:
METASTATIC CARCINOMA PRESENT IN THREE OF FIVE LYMPH NODES (3/5).
- (D) RIGHT LEVEL 3:
Adipose tissue, no tumor present.
- (E) RIGHT LEVEL 2B:
Two lymph nodes, no tumor present.
- (F) LEFT NECK 1B:
METASTATIC CARCINOMA PRESENT IN ONE OF FOUR LYMPH NODES (1/4).
Salivary gland, no tumor present.
- (G) LEFT NECK, LEVEL 2:
METASTATIC CARCINOMA PRESENT IN ONE OF FIVE LYMPH NODES (1/5).
- (H) LEFT NECK, LEVEL 3:
Fibroadipose tissue, no lymph node or tumor present.
- (I) LEFT NECK, LEVEL 2B:
Four lymph nodes, no tumor present.
- (J) LEFT DISTAL MENTAL NERVE:
Nerve and fibroadipose tissue, no tumor present.
- (K) RIGHT DISTAL MENTAL NERVE:
Nerve and fibroconnective tissue, no tumor present.
- (L) LEFT DISTAL INGUINAL NERVE:
Ductular structures, no tumor or nerve identified.
- (M) RIGHT LINGUAL NERVE:
Nerve and ganglia, no tumor present.
- (N) RIGHT DISTAL HYPOGLOSSAL NERVE:
Blood vessel, no nerve or tumor present.
- (O) LEFT PROXIMAL ALVEOLAR NERVE:
Nerve, no tumor present.
- (P) RIGHT PROXIMAL ALVEOLAR NERVE:
Nerve and blood vessel, no tumor present.
- (Q) RIGHT CENTRAL TONGUE:
No tumor present.
- (R) LEFT CENTRAL TONGUE:
No tumor present.
- (S) LEFT BUCCAL MUCOSA:
No tumor present.
- (T) RIGHT BUCCAL MUCOSA:

[page 2 of 5]
- No tumor present.
- (U) RIGHT FLOOR OF MOUTH:
No tumor present.
- (V) LEFT FLOOR OF MOUTH:
No tumor present.
- (W) RIGHT ORAL LABIA:
METASTATIC CARCINOMA INVOLVING LYMPHOVASCULAR SPACE.
- (Y) LEFT ORAL LABIA:
No tumor present.
- (Z) ANTERIOR MANDIBLE, FLOOR OF MOUTH:
SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.
TUMOR INVOLVED FULL THICKNESS OF TISSUE SECTIONS (1.4 CM).
PERINEURAL AND LYMPHOVASCULAR INVASION IS IDENTIFIED.
Bone sections are pending and supplemental report will follow.
- (AA) NEW RIGHT ORAL LABIAL MARGIN:
METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACES.
- (BB) RIGHT LATERAL SECOND RE-EXCISION:
SMALL FOCUS OF METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACE.
- (CC) ANTERIOR RIGHT SECOND RE-EXCISION:
METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACE AT INKED MARGIN.

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

- (A) RIGHT NECK DISSECTION, LEVEL 1A - A segment of adipose tissue, 3.0 x 2.0 x 2.0 cm) with one lymph node (0.8 x 0.5 x 0.5 cm).
SECTION CODE: A1, one bisected lymph node [REDACTED]
- (B) RIGHT NECK DISSECTION, LEVEL 1B - A submandibular salivary gland (2.5 x 2.0 x 1.5 cm) with attached adipose tissue and two lymph nodes (1.5 cm in diameter, each). The lymph nodes are grossly involved by tumor. The submandibular gland is unremarkable.
SECTION CODE: B1, representative section of one lymph node; B2, representative section of one lymph node; B3, representative section of salivary gland. [REDACTED]
- (C) RIGHT LEVEL 2A - A fragment of golden tan fatty tissue, 5.0 cm in greatest dimension. Multiple lymph nodes are dissected.
SECTION CODE: C1, three lymph nodes; C2, two grossly positive nodes (largest, 1.4 cm diameter); C3, one node. [REDACTED]
- (D) RIGHT LEVEL 3 - A golden tan-red fatty fragment of tissue, 5.0 cm in greatest dimension. No definite lymph nodes are identified grossly. The specimen is submitted in toto in D1-D3. [REDACTED]

[page 3 of 5]
(E) RIGHT LEVEL 2B - A 2.7 cm fragment of golden tan fatty tissue. One lymph node is grossly identified. The specimen is submitted in toto in E.

(F) LEFT NECK 1B - A tan rounded salivary gland (4.5 x 3.5 x 1.0 cm) and multiple lymph nodes ranging from 0.8 x 0.6 x 0.2 cm to 1.2 x 1.2 x 0.6 cm.

SECTION CODE: F1, one lymph node; F2-F4, one bisected lymph node each; F5, representative section from salivary gland.

(G) LEFT NECK, LEVEL 2 - Multiple lymph node (0.5 x 0.5 x 0.3 to 1.8 x 0.6 x 0.5 cm).

SECTION CODE: G1, proximal three possible lymph nodes; G2, one bisected lymph node; G3, one bisected lymph node.

(H) LEFT NECK, LEVEL 3 - A fragment of tan fibroadipose tissue (6.0 x 2.5 x 0.4 cm). No lymph node is identified. Submitted entirely in H1-H4.

(I) LEFT NECK LEVEL 2B - A fragment of fibroadipose tissue (2.5 x 1.0 x 0.5 cm). One possible lymph node is identified (0.6 cm in diameter).

SECTION CODE: i1, one possible lymph node; i2, remainder of tissue.

(J) LEFT DISTAL MENTAL NERVE - A tan irregular fibrofatty tissue fragment (1.0 x 0.8 x 0.3 cm). Entire specimen is submitted for frozen section in cassette J.

*FS/DX: NERVE AND FIBROCONNECTIVE TISSUE, NO TUMOR PRESENT.

(K) RIGHT DISTAL MENTAL NERVE - A single portion of soft, tan tissue (1.9 x 0.1 x 0.1 cm) is entirely submitted for frozen section in K.

*FS/DX: NERVE AND FIBROCONNECTIVE TISSUE, NO TUMOR PRESENT.

(L) LEFT DISTAL INGUINAL NERVE - A single portion of soft, tan tissue (0.8 x 0.3 x 0.1 cm) submitted entirely for frozen section in L.

*FS/DX: DUCT, NO TUMOR OR NERVE IDENTIFIED.

(M) RIGHT LINGUAL NERVE - A single portion of soft, tan tissue (0.7 x 0.2 x 0.1 cm) is submitted entirely for frozen section in M.

*FS/DX: NERVE AND GANGLIA, NO TUMOR PRESENT.

(N) RIGHT DISTAL HYPOGLOSSAL NERVE - A fragment of tan soft tissue (0.4 x 0.2 x 0.2 cm). Submitted entirely in N for frozen section.

*FS/DX: BLOOD VESSEL, NO NERVE OR TUMOR IDENTIFIED.

(O) LEFT PROXIMAL ALVEOLAR NERVE - A segment of tan soft tissue (0.4 x 0.2 x 0.1 cm). Submitted entirely for frozen section in O.

*FS/DX: NERVE, NO TUMOR PRESENT.

(P) RIGHT PROXIMAL ALVEOLAR NERVE - Three fragments of tan soft tissue (0.5 x 0.1 x 0.1 cm in aggregate). Submitted entirely for frozen section in P.

*FS/DX: NERVE AND BLOOD VESSEL, NO TUMOR PRESENT.

(Q) RIGHT VENTRAL TONGUE - A fragment of tan soft tissue (1.0 x 0.2 x 0.2 cm). Submitted entirely for frozen section in Q.

*FS/DX: NO TUMOR PRESENT.

(R) LEFT VENTRAL TONGUE - A fragment of tan soft tissue (1.5 x 0.1 x 0.1 cm). Submitted entirely for frozen section in R.

*FS/DX: NO TUMOR PRESENT.

(S) LEFT BUCCAL MUCOSA - A fragment of pink-tan soft tissue (1.5 x 0.1 x 0.1 cm). Submitted entirely for frozen section in S. YG/kf

*FS/DX: NO TUMOR PRESENT.

(T) RIGHT BUCCAL MUCOSA - A fragment of tan soft tissue (1.7 x 0.2 x 0.3 cm). Submitted entirely for frozen section in T.

[page 4 of 5]
[REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(U) RIGHT FLOOR OF MOUTH – A 0.9 x 0.7 x 0.5 cm pink-red fragment of tissue, in toto for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(V) LEFT FLOOR OF MOUTH – A 0.8 x 0.6 x 0.5 cm fragment of red-pink tissue, in toto for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT.

(W) RIGHT ORAL LABIA – A 1.8 x 0.4 x 0.3 cm fragment of red-tan tissue, in toto for frozen section. [REDACTED]

*FS/DX: METASTATIC CARCINOMA INVOLVING LYMPHOVASCULAR SPACE. [REDACTED]

(Y) LEFT ORAL LABIA – A 1.6 x 0.5 x 0.4 cm fragment of pink-tan tissue, in toto for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(Z) ANTERIOR MANDIBLE, FLOOR OF MOUTH – A 7.0 x 4.5 x 3.5 cm anterior mandibulectomy specimen with floor or mouth and underlying soft tissue and skeletal muscle.

The mucosally covered aspect measures 6.0 x 3.5 cm. There is a 5.0 x 2.0 x 3.5 cm irregular, variegated light tan-red tumor mass ulcerating the mucosal surface and centered roughly on the midline. The mucosal margins are grossly free. The inferior, anterior mandible just to the left of the midline is eroded 2.0 x 1.0 x 1.0 cm in extent. The bone is sent to the bone laboratory for further processing.

Tumor and normal mucosa is given for tumor bank and research protocol.

INK CODE: None.

SECTION CODE: Z1-Z15, AP sections of mucosa and tumor, right to left; Z16, Z17, tumor and soft tissue. [REDACTED]

(AA) NEW RIGHT ORAL LABIA MARGIN, INK AT TRUE MARGIN - A single portion of soft, tan tissue with overlying mucosa (2.5 x 0.9 x 0.3 cm) has blue ink designating the true margin.

INK CODE: The true margin is re-inked in black.

SECTION CODE: AA1-AA4, perpendicular true margin (two pieces each) entirely for frozen section. [REDACTED]

*FS/DX: METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACES AT THE INKED MARGIN. [REDACTED]

(BB) RIGHT LATERAL SECOND RE-EXCISION, INK AT TRUE MARGIN – A fragment of tan soft tissue (2.2 x 1.0 x 0.3 cm).

The true margin is re-inked in black. Specimen is serially sectioned and submitted entirely in BB1-BB3 for frozen section. YG/kf

*FS/DX: SMALL FOCUS OF METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACE. [REDACTED]

(CC) ANTERIOR RIGHT SECOND RE-EXCISION, INKED AT TRUE MARGIN – A fragment of pink-tan soft tissue (1.5 x 1.2 x 1.3 cm). The inked true margin is re-inked in black. Serially sectioned and submitted entirely in CC1 and CC2 for frozen section.

[REDACTED] *FS/DX: METASTATIC CARCINOMA IN LYMPHOVASCULAR SPACE AT THE INKED MARGIN. [REDACTED]

CLINICAL HISTORY

None given.

[REDACTED]

"Some tests reported here may have been developed and performance characteristics determined by [REDACTED] approved by the U.S. Food and Drug Administration."

[REDACTED] These tests have not been specifically cleared or

Released by: [REDACTED]

[page 5 of 5]
ADDENDUM

Addendum completed by [REDACTED]
[REDACTED]

DIAGNOSIS

(Z) **ANTERIOR MANDIBLE FLOOR OF MOUTH**
SQUAMOUS CELL CARCINOMA INVOLVING BONE, MARGINS FREE OF TUMOR.

[REDACTED]

Released by [REDACTED]

Source: NCI Genomic Data Commons file 94b00a08-f5b8-4b50-a6b6-1f775977355e (TCGA-CV-6936.781C78D3-0FB3-496F-B5B3-2AAA32BEBE84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).